Gene-level copy-number profile of tumor specimen ALCH-AFER-TTP1-A from ALCHEMIST case ALCH-AFER, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,705 days).
Specimen ALCH-AFER-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1e063e93-613d-45a6-8cfd-20b19d4cd135.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFER-NB7-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/9e21fa38-c664-416d-a2e3-cc54b6aae798

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 7,571; copy number 2: 44,904; copy number 3: 5,725; copy number 4: 148; copy number 5: 21; copy number 6: 4; copy number 7: 1; copy number 8: 4; copy number 9: 1; copy number 14: 1; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,211,340–1,214,153, 1 gene: TNFRSF4.
- chr1:1,253,909–1,273,864, 1 gene: UBE2J2.
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–1): PRAMEF29P.
- chr1:13,222,705–13,248,652, 2 genes: PRAMEF18, PRAMEF31P.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr17:3,636,459–3,663,103, 2 genes (within-gene range 0–2): CTNS, AC027796.4.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.
- chr20:30,214,765–30,214,976, 1 gene: CFTRP3.
- chr20:64,034,344–64,039,962, 1 gene (within-gene range 0–1): C20orf204.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,203,508–1,206,592, 1 gene, copy number 14: TNFRSF18.
- chr1:1,232,237–1,251,334, 3 genes, copy number 5–7: B3GALT6, C1QTNF12, AL162741.1.
- chr1:1,292,390–1,309,609, 2 genes, copy number 5 (within-gene range 4–18): ACAP3, MIR6726.
- chr1:1,331,280–1,349,418, 3 genes, copy number 6–8 (within-gene range 6–10): TAS1R3, DVL1, MIR6808.
- chr1:1,420,245–1,427,787, 2 genes, copy number 6 (within-gene range 3–6): AL391244.1, TMEM88B.
- chr4:1,009,936–1,026,898, 1 gene, copy number 6: FGFRL1.
- chr5:850,291–919,357, 3 genes, copy number 5 (within-gene range 4–5): BRD9, TRIP13, AC122719.3.
- chr11:65,367,438–65,383,701, 2 genes, copy number 5: AP000944.1, SLC25A45.
- chr16:560,394–565,529, 1 gene, copy number 20: PRR35.
- chr19:984,332–1,106,791, 12 genes, copy number 5: WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4.
- chr21:43,446,601–43,479,534, 3 genes, copy number 8–9: LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 7,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
